Surgical pathology report (de-identified scan), TCGA case TCGA-RP-A694, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site St. Joseph's Hospital AZ, specimen TCGA-RP-A694-06A (Metastatic).

Addendum Discussion: Special stains are performed on parts 2 and 3. The neoplastic cells are immunoreactivity for both S-100 and Melan-A consistent with metastatic melanoma.

Left parietal brain tumor

ICD-O-3
Melanoma, malignant NOS
8720/3
Site (L) Brain parietal lobe
Q71.3
JW 6/28/13

Sections demonstrate markedly hypercellular neoplasm consisting of sheets of moderately atypical tumor cells. The neoplastic cells exhibit moderate nuclear pleomorphism, variably prominent eosinophilic nucleoli and abundant weakly eosinophilic cytoplasm. Mitotic figures are numerous. Sheets of confluent tumor necrosis are present. Scattered hemosiderin-laden macrophages are identified consistent with chronic hemorrhage. There is a background of acute hemorrhage, as well. The adjacent brain parenchyma is gliotic and edematous.

Agency	Yes	No
☒ Disqualified ☐ Qualified	☐ Disqualified ☐ Qualified	
Date Reviewed: 4/18/13 Signature: [Signature]		

Source: NCI Genomic Data Commons file 25d5220f-d6be-4893-9857-2252a140e320 (TCGA-RP-A694.3A14A7BA-1435-4A30-878D-ED7591B67227.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).